Somatic mutation profile of tumor specimen 2f2e5477-42a4-4906-a943-bf7f80 (aliquot CPT0051690010) from CPTAC case 11LU035, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: GX; Age at diagnosis: 59.3 years (21,677 days).
Specimen 2f2e5477-42a4-4906-a943-bf7f80: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf6f7b60-8614-44cf-b5c6-051a4857c683.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 6b328a7b-2d97-4a02-8a6c-89f96a (Blood Derived Normal), aliquot CPT0034540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b18d9782-7ddc-4ad5-83c7-1ccebd8d66a3

The open-access MAF lists 97 somatic variants for this specimen: 61 protein-altering or splice-affecting, 21 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 21, Intron 7, RNA 4, 3'UTR 4, Frame Shift Del 3, Splice Site 2, Splice Region 2, Frame Shift Ins 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 46/235 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.8620G>C p.A2874P | Missense Mutation (SNP) | VAF 121/403 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as rs772827989, COSV60924961; called by muse, mutect2, varscan2
- ARHGAP32 | c.2444G>A p.G815D (on ENST00000310343 / NM_001378025.1; = p.G466D on NM_014715.4) | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs761823318, COSV59849840; called by muse, mutect2, varscan2
- BAHCC1 | c.2081G>T p.G694V | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); catalogued as COSV57030948; called by muse, mutect2, varscan2
- BCORL1 | c.4306-1G>T p.X1436_splice | Splice Site (SNP) | VAF 52/154 reads (34%) | catalogued as COSV99500570; called by muse, mutect2, varscan2
- CLEC14A | c.793G>T p.D265Y | Missense Mutation (SNP) | VAF 89/243 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs780001182, COSV60562609; called by muse, varscan2
- DDI2 | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs890895394; called by muse, mutect2, varscan2
- ERICH6 | c.1058T>C p.M353T | Missense Mutation (SNP) | VAF 61/171 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as rs748980736; called by muse, mutect2, varscan2
- FAM155B | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.274); catalogued as rs770211531, COSV52936224, COSV99368068; called by muse, mutect2, varscan2
- FLNA | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61051151; called by muse, mutect2
- OR2T10 | c.719C>A p.T240N | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57897190; called by muse, mutect2, varscan2
- OR5P3 | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 14/229 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.601); catalogued as COSV60429983; called by muse, mutect2
- PPP1R21 | c.40G>C p.A14P | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV54286620; called by muse, mutect2, varscan2
- RABGAP1L | c.2121G>C p.K707N | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52279382; called by muse, mutect2, varscan2
- RAP2C | c.282del p.K94Nfs*3 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as COSV61683132, COSV61683517; called by mutect2, pindel, varscan2
- SASH3 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.936); catalogued as rs1428400431, COSV100795318; called by muse, mutect2, varscan2
- SFTPC | c.436-1G>A p.X146_splice | Splice Site (SNP) | VAF 67/530 reads (13%) | catalogued as rs937375406; called by muse, mutect2, varscan2
- SLC5A8 | c.1480G>T p.E494* | Nonsense Mutation (SNP) | VAF 30/142 reads (21%) | catalogued as rs1176077061, COSV73310428, COSV73311196; called by muse, varscan2
- TSHZ3 | c.896A>T p.H299L | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53680914; called by muse, mutect2, varscan2
- AFF3 | c.737A>G p.D246G | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); called by muse, mutect2
- AP4E1 | c.2809G>A p.D937N | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- ARFGAP3 | c.972G>T p.M324I | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ARID2 | c.418+1dup | Frame Shift Ins (INS) | VAF 34/126 reads (27%) | called by mutect2, pindel
- BNC1 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 37/147 reads (25%) | called by muse, mutect2, varscan2
- BUB1B | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 104/359 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C2orf66 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- CA13 | c.516T>A p.G172= | Splice Region (SNP) | VAF 14/130 reads (11%) | called by muse, varscan2
- CDK5RAP2 | c.5257_5261delinsC p.I1753Qfs*23 | Frame Shift Del (DEL) | VAF 47/150 reads (31%) | called by pindel, varscan2*
- CMYA5 | c.6272G>T p.R2091M | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); called by muse, mutect2
- COL3A1 | c.2884C>T p.P962S | Missense Mutation (SNP) | VAF 21/238 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, mutect2
- DNAH14 | c.4592C>T p.S1531L (on ENST00000445597; = p.S1936L on NM_001367479.1) | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ERVV-2 | c.837dup p.V280Cfs*9 | Frame Shift Ins (INS) | VAF 100/464 reads (22%) | called by mutect2, pindel, varscan2
- FBN2 | c.2792C>T p.P931L | Missense Mutation (SNP) | VAF 154/547 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMCN1 | c.7945A>G p.T2649A | Missense Mutation (SNP) | VAF 14/420 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- INPP5E | c.1415T>C p.V472A | Missense Mutation (SNP) | VAF 101/406 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- KIAA1614 | c.463A>T p.S155C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by mutect2, varscan2
- KRTAP10-4 | c.551G>T p.S184I | Missense Mutation (SNP) | VAF 84/910 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.519); called by muse, mutect2
- KRTAP10-6 | c.551G>T p.S184I | Missense Mutation (SNP) | VAF 52/521 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.26); called by mutect2, varscan2
- KTI12 | c.922C>G p.R308G | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- LRP1B | c.11889G>C p.L3963F | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- MAP3K10 | c.800A>G p.Y267C | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH13 | c.1492C>A p.L498M | Missense Mutation (SNP) | VAF 49/546 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- NEDD4 | c.2739C>T p.H913= (on ENST00000508342 / NM_001284338.1; = p.H494= on NM_006154.4) | Splice Region (SNP) | VAF 52/200 reads (26%) | called by muse, mutect2, varscan2
- NEIL3 | c.779G>T p.R260I | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.059); called by muse, mutect2
- NEIL3 | c.780A>C p.R260S | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2
- OR2T12 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 27/276 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OR52A5 | c.380C>A p.A127D | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRDM1 | c.2113C>A p.H705N | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PRSS56 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- PXDN | c.3352C>T p.L1118F | Missense Mutation (SNP) | VAF 124/593 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PXDN | c.3166G>T p.G1056C | Missense Mutation (SNP) | VAF 113/366 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- RAET1G | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by mutect2, varscan2
- RYR2 | c.3681del p.F1227Lfs*25 | Frame Shift Del (DEL) | VAF 45/389 reads (12%) | called by pindel, varscan2
- RYR3 | c.7828C>A p.P2610T (on ENST00000389232; = p.P2611T on NM_001036.6) | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SAA2 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- SLC46A3 | c.114C>G p.N38K | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- TPO | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 36/442 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.406); called by muse, mutect2
- TWIST1 | c.540C>A p.H180Q | Missense Mutation (SNP) | VAF 56/314 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- WASHC3 | c.497T>C p.L166P | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- ZNF721 | c.2256G>C p.Q752H (on ENST00000338977; = p.Q764H on NM_133474.4) | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.01); called by muse, mutect2
- ZSCAN1 | c.94A>G p.R32G | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- B3GALT2 | c.948T>A p.G316= | Silent (SNP) | VAF 26/220 reads (12%) | called by muse, mutect2, varscan2
- CTSK | c.456C>G p.L152= | Silent (SNP) | VAF 97/423 reads (23%) | catalogued as COSV55013145; called by muse, mutect2, varscan2
- FBN1 | c.4992C>T p.Y1664= | Silent (SNP) | VAF 56/400 reads (14%) | called by muse, mutect2, varscan2
- GLI3 | c.4053C>T p.T1351= | Silent (SNP) | VAF 105/882 reads (12%) | called by muse, mutect2, varscan2
- IQCH | c.1539A>G p.L513= | Silent (SNP) | VAF 33/200 reads (17%) | called by muse, mutect2, varscan2
- KIAA0319L | c.3111C>T p.T1037= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as COSV57848330; called by muse, mutect2, varscan2
- KIF13B | c.4287C>T p.L1429= | Silent (SNP) | VAF 27/197 reads (14%) | called by muse, mutect2, varscan2
- LAMB4 | c.1941G>A p.E647= | Silent (SNP) | VAF 59/314 reads (19%) | called by muse, mutect2, varscan2
- LSAMP | c.711C>G p.L237= | Silent (SNP) | VAF 64/209 reads (31%) | called by muse, mutect2, varscan2
- OR52A5 | c.381C>A p.A127= | Silent (SNP) | VAF 29/138 reads (21%) | called by muse, mutect2, varscan2
- PCF11 | c.2346A>T p.G782= | Silent (SNP) | VAF 79/385 reads (21%) | called by muse, mutect2, varscan2
- PPFIA4 | c.1455G>A p.E485= (on ENST00000447715; = p.E460= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- PPP6R3 | c.1380C>T p.H460= (on ENST00000393800 / NM_001352375.2; = p.H409= on NM_018312.5) | Silent (SNP) | VAF 18/236 reads (8%) | catalogued as rs768263774; called by muse, mutect2
- SEPTIN1 | c.1224C>T p.G408= (on ENST00000321367; = p.G361= on NM_052838.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs779596462, COSV58443453; called by muse, mutect2, varscan2
- SLC45A2 | c.1506G>T p.G502= | Silent (SNP) | VAF 360/1030 reads (35%) | called by muse, mutect2, varscan2
- SLC9A8 | c.1377C>T p.T459= | Silent (SNP) | VAF 31/358 reads (9%) | called by muse, mutect2
- SORBS3 | c.1806G>A p.L602= | Silent (SNP) | VAF 22/190 reads (12%) | called by muse, mutect2, varscan2
- SYT10 | c.567T>C p.F189= | Silent (SNP) | VAF 50/164 reads (30%) | catalogued as rs765649332; called by muse, mutect2
- TBX5 | c.294G>A p.T98= | Silent (SNP) | VAF 132/494 reads (27%) | catalogued as rs769736865, COSV59859074; called by muse, varscan2
- TOPAZ1 | c.1779T>C p.D593= | Silent (SNP) | VAF 33/125 reads (26%) | called by muse, mutect2, varscan2
- ZNF729 | c.2514C>A p.A838= | Silent (SNP) | VAF 42/268 reads (16%) | called by muse, mutect2, varscan2
- AC132807.2 | n.256T>A | RNA (SNP) | VAF 50/149 reads (34%) | called by muse, mutect2, varscan2
- ACSS3 | c.*4443C>A | 3'UTR (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+4106G>C | Intron (SNP) | VAF 43/108 reads (40%) | called by muse, mutect2, varscan2
- CDK5RAP2 | c.4727-30G>T | Intron (SNP) | VAF 64/251 reads (25%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*2730C>A | 3'UTR (SNP) | VAF 61/792 reads (8%) | called by muse, mutect2
- CLSTN1 | c.2748+64G>T | Intron (SNP) | VAF 18/118 reads (15%) | called by muse, varscan2
- GRIK1 | c.1207-17T>A | Intron (SNP) | VAF 49/252 reads (19%) | called by muse, mutect2, varscan2
- GUCY1B2 | n.1571G>A | RNA (SNP) | VAF 11/83 reads (13%) | catalogued as rs775062926; called by muse, mutect2, varscan2
- HSP90AA4P | n.2010G>T | RNA (SNP) | VAF 21/263 reads (8%) | called by muse, mutect2
- HTR3A | c.*60C>A | 3'UTR (SNP) | VAF 84/371 reads (23%) | called by muse, mutect2, varscan2
- LMNA | c.1381-11C>T | Intron (SNP) | VAF 56/672 reads (8%) | called by muse, mutect2
- MYPN | c.*373C>T | 3'UTR (SNP) | VAF 54/161 reads (34%) | called by muse, mutect2, varscan2
- NDE1 | c.1030+2937A>T | Intron (SNP) | VAF 32/228 reads (14%) | called by muse, mutect2, varscan2
- PRRX1 | c.599+14C>A | Intron (SNP) | VAF 11/115 reads (10%) | called by muse, mutect2
- TUBB7P | n.935C>G | RNA (SNP) | VAF 37/496 reads (7%) | called by muse, mutect2
